Somatic mutation profile of tumor specimen 0DTYB6 from CCDI case PBCKEG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 0.5 years (189 days).
Specimen 0DTYB6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a882164b-75f8-42d2-98f1-3b186cf981e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTYAY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/331cb7a9-e96e-49ba-8c87-951b5c068529

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Frame Shift Ins 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNH7 | c.474dup p.G159Wfs*31 | Frame Shift Ins (INS) | VAF 117/589 reads (20%) | catalogued as COSV100037319; called by mutect2, varscan2
- SYDE2 | c.1828A>G p.M610V | Missense Mutation (SNP) | VAF 183/505 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs369066522; called by muse, mutect2, varscan2
- DENND4A | c.1953+95T>A | Intron (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 26/171 reads (15%) | called by muse, varscan2
